Gene-level copy-number profile of tumor specimen TCGA-F7-A50G-01A from TCGA case TCGA-F7-A50G, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 66.5 years (24,285 days).
Specimen TCGA-F7-A50G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.e4f7acf8-db3f-4046-b5fd-eb3c62564123.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-F7-A50G-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/74ef60bb-c903-4c8f-8e9c-90c8343414af

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 2,437; copy number 2: 23,158; copy number 3: 29,196; copy number 4: 3,275; copy number 5: 496; copy number 6: 317; copy number 7: 713; copy number 9: 88; copy number 12: 18; copy number 24: 43; copy number 34: 8; copy number 40: 37; copy number 45: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-F7-A50G-01A-11D-A25X-01): tumor purity 0.37, ploidy 2.72, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,638,285–22,128,103, 16 genes (within-gene range 0–1): H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 917 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:14,475–20,622,499, 264 genes, copy number 7 (broad region; genes not listed).
- chr9:20,683,304–20,716,188, 2 genes, copy number 7: FOCAD-AS1, MIR491.
- chr9:23,500,691–43,045,120, 447 genes, copy number 7 (broad region; genes not listed).
- chr12:19,089,151–30,321,617, 186 genes, copy number 9–45 (broad region; genes not listed).
- chr17:15,748,703–16,045,015, 16 genes, copy number 12: AC005324.5, AC005324.1, CDRT15P2, ZSWIM5P1, RNA5SP436, IL6STP1, MEIS3P1, AC015922.2, AC015922.3, AC015922.1, LINC02087, SPECC1P1, ADORA2B, ZSWIM7, TTC19, AC002553.2.
- chr17:16,040,472–16,044,961, 2 genes, copy number 12: AC002553.1, RPLP1P11.

Autosomal genes at a single copy (total copy number 1): 358. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
